Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3866, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3866-01A (Primary Tumor).

Diagnosis/ Diagnoses

1. Mechanically altered liver tissue with sections of a regressively changed cyst with partially dystrophic wall calcification.
2. Subcapsular liver tissue with circumscribed, clearly regenerative, nodular hyperplasia and moderate steatosis.
3. Resected ileocolic sample with a moderately differentiated adenocarcinoma of the colorectal type, measuring max 4 cm, with infiltration of the tunica muscularis propria up to the border of the perimuscular fatty tissue. Tumor-free local lymph nodes. Tumor-free small and large intestine resection margins. Tumor-free mesenteric resection margin. Complete, scarred obliteration of the appendix with a condition following previous appendicitis.

The tumor stage is: pT2, pN0 (0/23), pMX; G2, L0, V0, R

Source: NCI Genomic Data Commons file 468cf329-9669-49e6-bb49-ce55f0a07781 (TCGA-AA-3866.546E3D57-4548-4776-AF98-A46DF3160A72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).